Surgical pathology report (de-identified scan), TCGA case TCGA-S7-A7WT, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University Hospital Motol, specimen TCGA-S7-A7WT-01A (Primary Tumor).

Gross:

Thinly fibrously encapsulated left adrenal tumor 90x60x40 mm with soft consistency. Weight 97 g. On cut, whole tumoral center with dark red color with mushy consistency. Material was procured into 6 blocks.

Micro:

Pheochromocytoma in the adipose tissue with focal metaplasia into brown adipose tissue and adrenal cortex remnants with diffuse and macronodular growth, edematous and with focal hemorrhages; degree of necrosis is substantially lower than previously thought from macroscopic view. Focal scarring and dystrophic calcification.

Immunohistochemistry:

S100 protein – sustentacular cells were found quite sporadically, majority of the tumor negative

CD34 – in well depicted endothelial cells clear abundant tumor vascularization. Two freely lying groups of tumoral cells in lumen of peripheral vessels do not fulfill unequivocal criteria to detect angioinvasion; this are more probably microfragments artificially due to high dyscohesion in the tumor.

MIB1<1%.

PASS:

Large nests or diffuse growth (>10% of tumor volume) 2

Central (middle of large nests) or confluent tumor necrosis 1

High cellularity 1

Cellular monotony

Tumor cell spindling (even if focal) 2

Mitotic figures >3/10 HPF

Atypical mitotic figure(s)

Extension into adipose tissue 1

Vascular invasion

Capsular invasion 1

Profound nuclear pleomorphism 1

Nuclear hyperchromasia 1

Total 11

Procurement date:

Confirmation date:

ICD-0-3
Pheochromocytoma, malignant NOS
8700/3
Site: Adrenal gland
C74.9
JW 10/9/13

Source: NCI Genomic Data Commons file ab661eed-8c6e-42ff-bbae-282aa88a87ad (TCGA-S7-A7WT.49CFC3B3-6294-4A00-B7A5-F9F763E017E4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).